Somatic mutation profile of tumor specimen TCGA-56-5898-01A (aliquot TCGA-56-5898-01A-11D-1632-08) from TCGA case TCGA-56-5898, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 69.7 years (25,441 days).
Specimen TCGA-56-5898-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 18781c9f-d5d2-433c-9cbe-d3cbc4c98292.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-56-5898-10A (Blood Derived Normal), aliquot TCGA-56-5898-10A-01D-1632-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3ccda446-4700-4259-939b-f9190f81a8e2

The open-access MAF lists 160 somatic variants for this specimen: 119 protein-altering or splice-affecting, 35 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 106, Silent 35, Nonsense Mutation 8, Intron 3, Frame Shift Del 3, RNA 2, Splice Site 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KARS1 | c.1430G>A p.R477H | Missense Mutation (SNP) | VAF 20/160 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs778748895, COSV56694747; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SOS1 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 25/88 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67677937; called by muse, mutect2, varscan2
- TP53 | c.488A>G p.Y163C | Missense Mutation (SNP) | VAF 15/46 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148924904, CM942135, COSV52663142, COSV52676381; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA6 | c.4595C>T p.P1532L | Missense Mutation (SNP) | VAF 99/256 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52646067; called by muse, mutect2, varscan2
- ADAM2 | c.824C>G p.S275* | Nonsense Mutation (SNP) | VAF 7/72 reads (10%) | catalogued as COSV55869301; called by muse, mutect2, varscan2
- ADCY8 | c.2716G>T p.A906S | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.062); catalogued as COSV53931186; called by muse, mutect2, varscan2
- ADGRD1 | c.1543T>A p.F515I | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.087); catalogued as COSV55459606; called by muse, mutect2, varscan2
- ADIPOQ | c.613C>A p.L205M | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57860180; called by muse, mutect2, varscan2
- ARHGEF7 | c.2260G>T p.D754Y (on ENST00000375741 / NM_001113511.2; = p.D733Y on NM_145735.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.903); catalogued as COSV54553016; called by muse, mutect2, varscan2
- ATAD3A | c.614G>A p.R205Q | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.311); catalogued as rs780667832, COSV59233534, COSV59236548; called by muse, mutect2, varscan2
- ATP6V0A4 | c.1400A>G p.N467S | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1344106831, COSV59481245; called by muse, mutect2, varscan2
- ATP7A | c.3316G>T p.G1106C | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58443151, COSV58455426; called by muse, mutect2, varscan2
- ATP7B | c.1253A>C p.E418A | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54445124; called by muse, mutect2, varscan2
- BEND2 | c.1295T>C p.L432S | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV66217543; called by muse, mutect2
- BTNL3 | c.1138C>A p.L380I | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.209); catalogued as COSV61566003; called by mutect2, varscan2
- C7 | c.2492C>A p.S831Y | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.17); catalogued as COSV57482318; called by muse, mutect2
- CA3 | c.292G>T p.G98C | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53411624; called by muse, mutect2, varscan2
- CALCR | c.1321T>A p.S441T (on ENST00000649521 / NM_001164737.2; = p.S425T on NM_001742.4) | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.23); catalogued as COSV64012720; called by muse, mutect2, varscan2
- CARMIL3 | c.2005C>T p.P669S | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV57728702, COSV57728713; called by muse, mutect2, varscan2
- CASQ1 | c.616C>A p.P206T | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63624624; called by muse, mutect2, varscan2
- CATSPERD | c.109A>G p.I37V | Missense Mutation (SNP) | VAF 50/133 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs750662137, COSV62263536; called by muse, mutect2, varscan2
- CD47 | c.785C>T p.A262V | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs754405285, COSV62528392; called by muse, mutect2
- CEP192 | c.6026A>C p.Q2009P | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV58071489; called by muse, varscan2
- CFAP126 | c.95T>A p.I32N | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.805); catalogued as COSV61369817; called by muse, mutect2, varscan2
- CFAP300 | c.598G>T p.D200Y | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71571016; called by muse, mutect2, varscan2
- CHIA | c.1259C>A p.S420Y (on ENST00000343320; = p.S312Y on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.553); catalogued as COSV58478755; called by muse, mutect2, varscan2
- CLHC1 | c.770T>G p.F257C | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV63427350; called by muse, mutect2, varscan2
- CLP1 | c.1219C>T p.R407C | Missense Mutation (SNP) | VAF 51/133 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs769708076, COSV57055974; called by muse, mutect2, varscan2
- CMA1 | c.391T>C p.F131L | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51626546; called by muse, mutect2, varscan2
- CMBL | c.34A>G p.I12V | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.182); catalogued as rs770734908, COSV56985540; called by muse, mutect2, varscan2
- CNTNAP2 | c.788C>A p.T263K | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.85); PolyPhen possibly damaging (0.783); catalogued as COSV62147587, COSV99080853; called by muse, mutect2, varscan2
- CNTNAP5 | c.2677C>T p.L893F | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.091); catalogued as rs1255951986, COSV70515541; called by muse, mutect2, varscan2
- CREB3L3 | c.214G>C p.D72H | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV50190148, COSV50282682; called by muse, mutect2, varscan2
- CRYBG3 | c.6145G>T p.V2049F | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.229); catalogued as COSV51716797; called by muse, mutect2, varscan2
- CYP2B6 | c.1404C>G p.I468M | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs772114611, COSV57845790; called by muse, mutect2, varscan2
- DCAF12L1 | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs1269956259, COSV64422903; called by muse, mutect2, varscan2
- DDC | c.380A>C p.E127A | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV63568246; called by muse, mutect2, varscan2
- DDC | c.379G>T p.E127* | Nonsense Mutation (SNP) | VAF 14/39 reads (36%) | catalogued as COSV63565580, COSV63568253; called by muse, mutect2, varscan2
- DSG1 | c.1883A>G p.D628G | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.372); catalogued as rs746988678, COSV57139896; called by muse, mutect2, varscan2
- DYRK1A | c.11G>A p.G4E | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV58297515; called by muse, mutect2, varscan2
- EGFLAM | c.520C>T p.Q174* | Nonsense Mutation (SNP) | VAF 16/112 reads (14%) | catalogued as COSV59319870; called by muse, varscan2
- EPB41L3 | c.2441G>C p.G814A | Missense Mutation (SNP) | VAF 52/155 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV59470285; called by muse, mutect2, varscan2
- EPHB1 | c.1271C>T p.S424F | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV101213189, COSV67673211; called by muse, mutect2, varscan2
- EPHB2 | c.73G>A p.D25N | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.951); catalogued as rs765772842, COSV101006869; called by mutect2, varscan2
- ERICH3 | c.2876T>C p.M959T | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs777512110, COSV58620571; called by muse, mutect2, varscan2
- EYS | c.1642C>T p.Q548* | Nonsense Mutation (SNP) | VAF 11/57 reads (19%) | catalogued as CM102715, COSV61001771; called by muse, mutect2, varscan2
- EYS | c.926G>T p.C309F | Missense Mutation (SNP) | VAF 14/171 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as COSV61001795; called by muse, mutect2
- FAT2 | c.12713C>G p.P4238R | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55831114; called by muse, mutect2, varscan2
- FOXG1 | c.989C>A p.T330N | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.142); catalogued as rs150277632, COSV100487012, COSV57399999; called by muse, mutect2, varscan2
- GDNF | c.298C>A p.P100T | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV58482312; called by muse, mutect2, varscan2
- GRPEL2 | c.559G>T p.G187C | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV61388367; called by muse, mutect2, varscan2
- HERC1 | c.1652G>C p.R551P | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71250630; called by muse, mutect2, varscan2
- IL1RAPL2 | c.994C>T p.H332Y | Missense Mutation (SNP) | VAF 38/71 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV61186661; called by muse, mutect2, varscan2
- INPPL1 | c.334G>C p.A112P | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV104402547, COSV53359890; called by muse, mutect2, varscan2
- KAT2B | c.760C>T p.R254C | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs751179221, COSV55431073; called by muse, varscan2
- KLHL1 | c.791G>A p.W264* | Nonsense Mutation (SNP) | VAF 21/102 reads (21%) | catalogued as COSV64767717, COSV64785959; called by muse, mutect2, varscan2
- LRP2BP | c.785G>T p.C262F | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as COSV60751194; called by muse, mutect2, varscan2
- LRRC7 | c.779T>C p.L260S (on ENST00000651989 / NM_001370785.2; = p.L227S on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV50648612; called by muse, mutect2, varscan2
- LRRCC1 | c.1813G>T p.D605Y | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.073); catalogued as COSV64486239; called by muse, mutect2, varscan2
- MAML1 | c.1300G>T p.G434W | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52989270; called by muse, mutect2, varscan2
- MFSD2A | c.1254G>T p.M418I (on ENST00000372809 / NM_001136493.3; = p.M405I on NM_032793.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV65686730; called by muse, mutect2, varscan2
- MPP5 | c.619G>C p.E207Q | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as COSV55533237; called by muse, mutect2, varscan2
- MYO16 | c.5257G>C p.G1753R | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as COSV62763618; called by muse, mutect2, varscan2
- MYOCD | c.267G>C p.E89D | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as COSV58513609; called by muse, mutect2, varscan2
- MYT1L | c.660G>T p.R220S | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.299); catalogued as COSV67734348; called by muse, mutect2, varscan2
- NLRP2 | c.3148C>T p.P1050S | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.3); catalogued as COSV54761241; called by muse, mutect2, varscan2
- NLRP5 | c.1384C>T p.R462C | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.731); catalogued as rs199475775, COSV66767095; ClinVar: not provided; called by muse, mutect2, varscan2
- NRROS | c.1357C>T p.P453S | Missense Mutation (SNP) | VAF 40/184 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1275076567, COSV60748076; called by muse, mutect2, varscan2
- ODF2 | c.2270A>G p.E757G (on ENST00000434106 / NM_153433.2; = p.E733G on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV63549220; called by muse, mutect2, varscan2
- OR11H4 | c.680C>A p.S227Y | Missense Mutation (SNP) | VAF 93/303 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV59561031; called by muse, mutect2, varscan2
- OR2T34 | c.712G>A p.G238S | Missense Mutation (SNP) | VAF 56/146 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.588); catalogued as rs779030084, COSV60901135, COSV60902204; called by muse, mutect2, varscan2
- OR4C46 | c.449G>T p.G150V | Missense Mutation (SNP) | VAF 53/180 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.77); catalogued as rs1404158661, COSV60221509; called by muse, mutect2, varscan2
- OR51I2 | c.623G>T p.G208V | Missense Mutation (SNP) | VAF 59/153 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.088); catalogued as rs1249208716, COSV58300485; called by muse, mutect2, varscan2
- OR8B4 | c.50T>C p.L17S | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.897); catalogued as COSV62070722; called by muse, mutect2, varscan2
- OTUD4 | c.1673C>T p.P558L (on ENST00000447906 / NM_001366057.1; = p.P493L on NM_001102653.1) | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.037); catalogued as COSV71382365; called by mutect2, varscan2
- PA2G4 | c.214A>T p.K72* | Nonsense Mutation (SNP) | VAF 7/64 reads (11%) | catalogued as COSV57264779; called by muse, mutect2, varscan2
- PCDH17 | c.3343G>T p.G1115C | Missense Mutation (SNP) | VAF 39/148 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.237); catalogued as COSV64980280; called by muse, mutect2, varscan2
- PDZD2 | c.7076C>T p.P2359L | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.212); catalogued as COSV56875065; called by muse, mutect2, varscan2
- PREX2 | c.4087+2T>A p.X1363_splice | Splice Site (SNP) | VAF 22/60 reads (37%) | catalogued as COSV55803021; called by muse, mutect2, varscan2
- PRKDC | c.4898G>T p.W1633L | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.354); catalogued as COSV58066095; called by muse, mutect2
- PRPF19 | c.1162T>C p.F388L | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.402); catalogued as COSV57129535; called by muse, mutect2, varscan2
- PTCHD4 | c.2118G>T p.W706C | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59777580; called by muse, mutect2, varscan2
- PTPRB | c.2968G>C p.V990L | Missense Mutation (SNP) | VAF 51/89 reads (57%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs1339428287, COSV54255776; called by muse, mutect2, varscan2
- PTPRO | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs760993815, COSV55514507; called by muse, mutect2, varscan2
- RAB3GAP1 | c.2254A>G p.R752G | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.129); catalogued as COSV51489792; called by muse, mutect2, varscan2
- RBM45 | c.1017G>C p.M339I (on ENST00000616198 / NM_001365579.1; = p.M337I on NM_152945.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.024); catalogued as COSV53722796; called by muse, mutect2, varscan2
- RNASE12 | c.187A>G p.K63E | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.749); catalogued as COSV60088475; called by muse, mutect2, varscan2
- RPS6KA2 | c.460-1G>T p.X154_splice | Splice Site (SNP) | VAF 6/55 reads (11%) | catalogued as COSV55831937; called by muse, mutect2, varscan2
- RYR2 | c.6912T>A p.F2304L | Missense Mutation (SNP) | VAF 39/248 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63718930; called by muse, mutect2, varscan2
- SLC12A6 | c.575A>G p.Y192C (on ENST00000354181 / NM_001365088.1; = p.Y141C on NM_005135.2) | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51633062; called by muse, mutect2, varscan2
- SMYD1 | c.8T>G p.I3R | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as COSV70226199; called by muse, mutect2, varscan2
- SOS2 | c.3818G>T p.R1273L | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.326); catalogued as COSV53575664, COSV99365163; called by muse, mutect2, varscan2
- STXBP2 | c.865G>T p.V289L | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV55405888; called by muse, mutect2, varscan2
- TAF1A | c.1273G>T p.D425Y | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as COSV61920228; called by muse, mutect2, varscan2
- TAS2R60 | c.135G>T p.E45D | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as COSV60332329; called by muse, mutect2
- TBL2 | c.838G>A p.A280T | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.87); catalogued as rs782001587, COSV59788201, COSV59788887; called by muse, mutect2, varscan2
- TCP1 | c.1454G>A p.W485* | Nonsense Mutation (SNP) | VAF 15/139 reads (11%) | catalogued as COSV58460648; called by muse, mutect2, varscan2
- THSD4 | c.2334G>A p.M778I | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.447); catalogued as COSV55986864; called by muse, mutect2, varscan2
- TMEM185A | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.636); catalogued as rs1335324061; called by muse, mutect2, varscan2
- TNKS1BP1 | c.1681C>G p.Q561E | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV64102926; called by muse, mutect2, varscan2
- TNR | c.3019C>T p.R1007W | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as rs774052903, COSV54873532; called by muse, mutect2, varscan2
- TOMM40L | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.55); PolyPhen benign (0.017); catalogued as rs752268797, COSV63469618; called by muse, mutect2, varscan2
- TRIM63 | c.528G>A p.M176I | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV65329593; called by muse, mutect2, varscan2
- TRPC5 | c.2368G>C p.A790P | Missense Mutation (SNP) | VAF 9/207 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.081); catalogued as COSV53304084; called by muse, mutect2
- TTK | c.1883G>T p.W628L | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV57887252; called by muse, mutect2, varscan2
- TTN | c.61403C>A p.P20468H (on ENST00000591111; = p.P13044H on NM_003319.4) | Missense Mutation (SNP) | VAF 34/197 reads (17%) | PolyPhen possibly damaging (0.875); catalogued as COSV60391647; called by muse, mutect2, varscan2
- TTN | c.61402C>A p.P20468T (on ENST00000591111; = p.P13044T on NM_003319.4) | Missense Mutation (SNP) | VAF 34/203 reads (17%) | PolyPhen possibly damaging (0.564); catalogued as COSV60391668; called by muse, mutect2, varscan2
- UGP2 | c.677T>C p.I226T | Missense Mutation (SNP) | VAF 27/214 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.101); catalogued as rs1356768880, COSV61430657; called by muse, mutect2, varscan2
- USH2A | c.11090C>A p.T3697K | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.122); catalogued as COSV56448677; called by muse, mutect2, varscan2
- VCAN | c.9762G>T p.Q3254H | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54118385; called by muse, mutect2, varscan2
- YARS2 | c.859G>T p.G287C | Missense Mutation (SNP) | VAF 37/157 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61402649; called by muse, mutect2, varscan2
- ZNF230 | c.31A>G p.K11E | Missense Mutation (SNP) | VAF 43/182 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV71273786; called by muse, mutect2, varscan2
- ZNF473 | c.2500A>G p.R834G | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs766241856, COSV54525417; called by muse, mutect2, varscan2
- ZNF804B | c.3584T>C p.V1195A | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as COSV60859461; called by muse, mutect2, varscan2
- FAT2 | c.337_341del p.D113Lfs*29 | Frame Shift Del (DEL) | VAF 23/119 reads (19%) | called by mutect2, pindel, varscan2
- GPHN | c.1148del p.G383Afs*21 (on ENST00000315266 / NM_001377519.1; = p.G416Afs*21 on NM_020806.5) | Frame Shift Del (DEL) | VAF 14/42 reads (33%) | called by mutect2, pindel*, varscan2
- IGHV1OR21-1 | c.85G>T p.E29* | Nonsense Mutation (SNP) | VAF 25/156 reads (16%) | called by muse, mutect2, varscan2
- TUBGCP5 | c.932G>T p.R311L | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- ULK1 | c.993_997del p.A332Hfs*20 | Frame Shift Del (DEL) | VAF 9/25 reads (36%) | called by mutect2, pindel
- ACAD11 | c.201T>C p.Y67= | Silent (SNP) | VAF 27/97 reads (28%) | catalogued as rs757328960, COSV53902317; called by muse, mutect2, varscan2
- AKAP9 | c.8967T>C p.Y2989= (on ENST00000359028; = p.Y2965= on NM_005751.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/63 reads (11%) | catalogued as COSV62359240; called by muse, mutect2
- APOB | c.4023C>A p.T1341= | Silent (SNP) | VAF 28/100 reads (28%) | catalogued as COSV51955805; called by muse, mutect2, varscan2
- ARHGAP32 | c.2205G>C p.L735= (on ENST00000310343 / NM_001378025.1; = p.L386= on NM_014715.4) | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as COSV59856652; called by muse, mutect2, varscan2
- ARL14 | c.156C>T p.I52= | Silent (SNP) | VAF 22/137 reads (16%) | catalogued as rs776701439, COSV100296450, COSV57900579; called by muse, mutect2, varscan2
- CCDC15 | c.1644C>T p.P548= | Silent (SNP) | VAF 69/239 reads (29%) | catalogued as rs750037111, COSV100776933; called by muse, mutect2, varscan2
- CDC23 | c.1710C>G p.P570= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV67510783; called by muse, mutect2, varscan2
- CLEC14A | c.513C>T p.C171= | Silent (SNP) | VAF 31/91 reads (34%) | catalogued as COSV60564574; called by muse, mutect2, varscan2
- CSMD2 | c.6744G>A p.R2248= | Silent (SNP) | VAF 16/85 reads (19%) | catalogued as COSV53970561; called by muse, mutect2, varscan2
- DYSF | c.4956C>T p.L1652= | Silent (SNP) | VAF 13/70 reads (19%) | catalogued as COSV50636632; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.1689C>T p.L563= | Silent (SNP) | VAF 501/563 reads (89%) | catalogued as COSV62571320; called by muse, mutect2, varscan2
- EPHX4 | c.1038G>C p.V346= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as COSV100952678, COSV64888898, COSV64890163; called by muse, mutect2, varscan2
- IQUB | c.2289T>A p.L763= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as COSV61243278; called by muse, mutect2, varscan2
- MAML1 | c.1299G>T p.T433= | Silent (SNP) | VAF 19/94 reads (20%) | catalogued as COSV52983327, COSV52989253; called by muse, mutect2, varscan2
- MAP2 | c.4227A>G p.K1409= | Silent (SNP) | VAF 19/79 reads (24%) | catalogued as COSV52310667; called by muse, mutect2, varscan2
- MRAS | c.48G>T p.L16= | Silent (SNP) | VAF 31/115 reads (27%) | catalogued as COSV56674845; called by muse, mutect2, varscan2
- MTUS2 | c.1311G>T p.V437= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV70914069, COSV70923968; called by muse, mutect2
- MYO19 | c.2277G>C p.R759= (on ENST00000614623 / NM_001163735.1; = p.R559= on NM_025109.5) | Silent (SNP) | VAF 4/13 reads (31%) | called by muse, mutect2, varscan2
- MYOZ3 | c.9C>A p.P3= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as COSV51741291; called by muse, mutect2, varscan2
- OR9Q2 | c.345G>T p.L115= | Silent (SNP) | VAF 35/138 reads (25%) | catalogued as COSV61111971, COSV61112893; called by muse, mutect2, varscan2
- PKNOX2 | c.420C>A p.V140= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as COSV53556448; called by muse, mutect2, varscan2
- PROP1 | c.51C>A p.V17= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as COSV57645595; called by muse, mutect2, varscan2
- RANGAP1 | c.189G>A p.V63= | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as COSV62364954; called by muse, mutect2, varscan2
- SASH3 | c.417G>A p.P139= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs201751439, COSV63556815; called by muse, mutect2, varscan2
- SIGLEC7 | c.1182C>A p.G394= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV58318182; called by muse, mutect2, varscan2
- SLC22A18 | c.1233C>G p.L411= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as COSV56542360; called by muse, mutect2, varscan2
- SLC5A10 | c.327G>C p.V109= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as COSV58762793; called by muse, mutect2, varscan2
- SLC6A3 | c.969C>A p.G323= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as COSV54370297; called by muse, mutect2, varscan2
- SLC9A8 | c.1059C>A p.T353= | Silent (SNP) | VAF 27/114 reads (24%) | catalogued as COSV64291879; called by muse, mutect2, varscan2
- STYK1 | c.579G>T p.V193= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as rs1488034813, COSV50015875; called by muse, mutect2, varscan2
- TMEM108 | c.1551C>T p.F517= | Silent (SNP) | VAF 36/288 reads (13%) | catalogued as COSV58865308, COSV58884772; called by muse, mutect2, varscan2
- TRH | c.483C>A p.P161= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV57015824; called by muse, mutect2, varscan2
- TRIM37 | c.1428A>G p.A476= | Silent (SNP) | VAF 69/109 reads (63%) | catalogued as rs1290058558, COSV51889376; called by muse, mutect2, varscan2
- TTN | c.16339C>T p.L5447= (on ENST00000591111; = p.L4520= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as COSV60391691; called by muse, mutect2, varscan2
- UGGT1 | c.2874A>G p.P958= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as rs752882702, COSV52142660; called by muse, mutect2, varscan2
- AC244258.1 | n.848G>C | RNA (SNP) | VAF 14/65 reads (22%) | called by muse, mutect2
- DST | c.4297-1255A>G | Intron (SNP) | VAF 33/137 reads (24%) | catalogued as COSV99753453; called by muse, mutect2, varscan2
- NRXN3 | c.989-7457A>G | Intron (SNP) | VAF 23/142 reads (16%) | catalogued as rs531795365; called by muse, mutect2, varscan2
- RNU6-104P | chr8:43304762 C>A | 3'Flank (SNP) | VAF 4/62 reads (6%) | called by muse, mutect2
- SNORD116-4 | n.37G>T | RNA (SNP) | VAF 25/134 reads (19%) | called by muse, mutect2, varscan2
- SV2C | c.581-20779C>A | Intron (SNP) | VAF 21/79 reads (27%) | called by muse, mutect2, varscan2
